Somatic mutation profile of tumor specimen C3N-00466-54 (aliquot CPT0023020001) from CPTAC case C3N-00466, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 45.8 years (16,720 days).
Specimen C3N-00466-54: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03fdafdd-0cd2-4b1b-a795-71ca5438d096.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00466-51 (Buccal Cell Normal), aliquot CPT0023130002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f41e1b1-f1df-4033-9193-55b705af08e9

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC7 | c.2564G>A p.R855H | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.184); catalogued as rs770227739, COSV56546084; called by muse, varscan2
